Somatic mutation profile of tumor specimen C3L-01248-01 (aliquot CPT0080300006) from CPTAC case C3L-01248, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 42.5 years (15,531 days).
Specimen C3L-01248-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 326d8288-b990-4470-8991-47182ddca145.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01248-71 (Blood Derived Normal), aliquot CPT0080340001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc130caa-1b5e-4db3-834d-4dc73a152a63

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1564837839, CD983505, COSV64289389, COSV64289854, COSV64294530, COSV64297160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.885_886del p.C296* | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs1564568350; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CDH20 | c.2090C>T p.T697M | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV53009196; called by muse, mutect2
- ATRX | c.5152_5153insA p.C1718* | Nonsense Mutation (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- CPSF2 | c.521_522insA p.D175* | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2, pindel
- EXOSC3 | c.464del p.P155Qfs*48 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel
- KLRF1 | c.581C>A p.S194* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- MYH11 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 36/802 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPARCL1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.335); called by muse, mutect2
- USP42 | c.1770G>T p.Q590H | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2
- AFDN | c.2451G>A p.A817= | Silent (SNP) | VAF 20/366 reads (5%) | catalogued as rs763860525; called by muse, mutect2
- TGM6 | c.648C>T p.Y216= | Silent (SNP) | VAF 38/599 reads (6%) | catalogued as rs140141767, COSV52482855; called by muse, mutect2
